CCDI case PBCMPD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/5f5fd3de-2447-4cd4-94f1-99685b9b89ec

Demographics
Sex at birth: male; Race: white.

Biospecimens (2 samples)
- Sample 0DVDUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVDV0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
